Somatic mutation profile of tumor specimen ALCH-B1OE-TTP1-A (aliquot ALCH-B1OE-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1OE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 58.3 years (21,294 days).
Specimen ALCH-B1OE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3500135c-3fe9-48b6-b9b1-9124777b7463.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1OE-NB1-A (Blood Derived Normal), aliquot ALCH-B1OE-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95380e42-cdab-4325-9ce6-a6ef3468a41d

The open-access MAF lists 204 somatic variants for this specimen: 148 protein-altering or splice-affecting, 36 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 124, Silent 36, Nonsense Mutation 13, Intron 7, RNA 7, Splice Site 6, 5'UTR 4, 3'UTR 2, Frame Shift Del 2, Splice Region 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 29/250 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- STK11 | c.407T>C p.M136T | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1060499958, CM011963, CM1312244, COSV100480034; ClinVar: pathogenic / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABL2 | c.2152T>A p.Y718N (on ENST00000502732 / NM_007314.4; = p.Y703N on NM_005158.5) | Missense Mutation (SNP) | VAF 40/253 reads (16%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.021); catalogued as rs773341075; called by muse, mutect2, varscan2
- ATM | c.8746G>T p.D2916Y | Missense Mutation (SNP) | VAF 53/339 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53760548; called by muse, mutect2, varscan2
- BRINP1 | c.2105G>C p.R702P | Missense Mutation (SNP) | VAF 19/296 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56297833; called by muse, mutect2
- CEP41 | c.508G>T p.D170Y | Missense Mutation (SNP) | VAF 42/442 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56221401; called by muse, mutect2
- CHST1 | c.190C>A p.L64I | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.27); catalogued as COSV57322912, COSV57323719; called by muse, mutect2, varscan2
- CLVS2 | c.925C>A p.L309I | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.978); catalogued as COSV99251904; called by muse, mutect2
- CNTNAP4 | c.3854C>A p.A1285D | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.691); catalogued as COSV56690733; called by muse, mutect2
- COL16A1 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 52/414 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as rs375268814, COSV54701089, COSV54701553; called by muse, mutect2, varscan2
- CSMD3 | c.3901G>C p.D1301H (on ENST00000297405 / NM_001363185.1; = p.D1197H on NM_052900.3) | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52180133, COSV52316033; called by muse, mutect2, varscan2
- DEF6 | c.1849G>T p.A617S | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as COSV57353132; called by muse, mutect2, varscan2
- DEPDC1 | c.1559G>A p.R520K | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1326692240, COSV63958476; called by muse, mutect2
- DNAH10 | c.3654A>G p.I1218M (on ENST00000409039; = p.I1157M on NM_207437.3) | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs369267564; called by muse, varscan2
- FBN2 | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 45/422 reads (11%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.007); catalogued as rs146807421; ClinVar: uncertain significance; called by muse, mutect2
- FMN1 | c.3776C>T p.S1259F (on ENST00000616417 / NM_001277313.2; = p.S1036F on NM_001103184.4) | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1198155837; called by muse, mutect2
- GOLGA6L2 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 24/293 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); catalogued as rs201237778; called by muse, mutect2
- HLA-DOB | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs1430990943; called by muse, mutect2, varscan2
- ILDR2 | c.553C>G p.P185A | Missense Mutation (SNP) | VAF 45/316 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV54835406; called by muse, mutect2, varscan2
- INCENP | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs781478310; called by muse, mutect2, varscan2
- INTS11 | c.1645G>A p.G549S | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.117); catalogued as rs756503541; called by muse, mutect2
- KMT2E | c.2743C>T p.R915W | Missense Mutation (SNP) | VAF 43/426 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs780716600, COSV57570081; called by muse, mutect2, varscan2
- KRT33A | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 44/480 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs536221397, COSV50370912, COSV99144957; called by muse, mutect2
- LLGL1 | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 8/121 reads (7%) | catalogued as rs1413321606, COSV100375094; called by muse, mutect2
- LRP1B | c.1991G>T p.W664L | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101252543, COSV101261383; called by muse, mutect2
- LRRIQ1 | c.4209+1del | Frame Shift Del (DEL) | VAF 9/83 reads (11%) | catalogued as COSV67833886; called by mutect2, pindel, varscan2
- MAST4 | c.826G>C p.A276P (on ENST00000403625 / NM_001164664.2; = p.A87P on NM_015183.3) | Missense Mutation (SNP) | VAF 27/308 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55119869; called by muse, mutect2
- MUC16 | c.36291del p.K12098Sfs*31 | Frame Shift Del (DEL) | VAF 36/230 reads (16%) | catalogued as COSV67501910; called by mutect2, pindel, varscan2
- OR2B6 | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV55128674; called by muse, mutect2, varscan2
- OR5B17 | c.832A>G p.M278V | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.06); catalogued as rs1565141675; called by muse, mutect2, varscan2
- OR5D13 | c.591C>A p.S197R | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100686745, COSV62334561; called by muse, mutect2, varscan2
- P2RY10 | c.901G>T p.D301Y | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50682005, COSV50686293; called by muse, mutect2
- PCDHGB2 | c.2033G>T p.R678L | Missense Mutation (SNP) | VAF 40/355 reads (11%) | SIFT tolerated (0.77); PolyPhen benign (0.018); catalogued as COSV53930536; called by muse, mutect2, varscan2
- PLA2G7 | c.677C>G p.A226G | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as rs201615539, COSV51262368; called by muse, varscan2
- PLXNA4 | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 20/120 reads (17%) | catalogued as rs1294000775, COSV100323282, COSV58142761; called by muse, mutect2
- POU4F2 | c.625G>C p.D209H | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV55586571; called by muse, varscan2
- PTPRH | c.3198G>A p.E1066= | Splice Region (SNP) | VAF 11/77 reads (14%) | catalogued as rs780040907, COSV54749954; called by muse, varscan2
- RTL1 | c.3352C>A p.P1118T | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.965); catalogued as COSV66017196; called by muse, mutect2, varscan2
- RYR2 | c.12746G>C p.R4249T | Missense Mutation (SNP) | VAF 60/602 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs756906888; called by muse, mutect2
- SELE | c.1594C>T p.R532W | Missense Mutation (SNP) | VAF 57/274 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs370418450, COSV60976108; called by muse, mutect2, varscan2
- SOX8 | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1473172780, COSV53509502; called by muse, mutect2, varscan2
- SPTBN2 | c.2413G>T p.A805S | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.153); catalogued as rs777593608; called by muse, mutect2, varscan2
- STUM | c.157G>T p.V53L | Missense Mutation (SNP) | VAF 42/300 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV64684559; called by muse, mutect2, varscan2
- SUN2 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.142); catalogued as rs1344825115, COSV53302403; called by muse, mutect2, varscan2
- TMEM198 | c.141G>T p.L47F | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as COSV60536184; called by muse, mutect2, varscan2
- TMEM259 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.034); catalogued as rs145798599, COSV52260976; called by muse, mutect2, varscan2
- TMX4 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs376577418; called by mutect2, varscan2
- TOPBP1 | c.1351G>T p.E451* | Nonsense Mutation (SNP) | VAF 19/275 reads (7%) | catalogued as COSV99604979; called by muse, mutect2
- TRIM58 | c.867C>G p.F289L | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as rs766750346, COSV100824859; called by muse, mutect2, varscan2
- VAV1 | c.272G>A p.S91N | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV100408740; called by muse, mutect2
- XAGE5 | c.124G>T p.D42Y | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100657805; called by muse, varscan2
- ZNF208 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV68106365; called by muse, mutect2, varscan2
- A2ML1 | c.3808G>A p.E1270K | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAMTS12 | c.1798G>T p.A600S | Missense Mutation (SNP) | VAF 33/335 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2
- ADAMTS17 | c.3127+1G>T p.X1043_splice | Splice Site (SNP) | VAF 4/52 reads (8%) | called by muse, mutect2
- AGMAT | c.526C>G p.H176D | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ALX1 | c.791G>T p.G264V | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- AMPD1 | c.997G>T p.V333L | Missense Mutation (SNP) | VAF 22/295 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- APBB3 | c.137A>C p.Y46S | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATG2B | c.999G>T p.M333I | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- ATP2C1 | c.1652G>T p.G551V | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2
- AZIN2 | c.615C>G p.D205E | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.134); called by muse, mutect2
- B3GNT4 | c.982T>A p.F328I | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2
- B4GALT1 | c.939A>T p.E313D | Missense Mutation (SNP) | VAF 31/282 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BRINP2 | c.1091T>C p.M364T | Missense Mutation (SNP) | VAF 25/620 reads (4%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- C10orf88 | c.881G>T p.C294F | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0.325); called by muse, mutect2
- CCDC93 | c.587C>G p.S196C | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2
- CDYL | c.1017C>A p.Y339* (on ENST00000328908 / NM_001368125.1; = p.Y285* on NM_004824.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 39/383 reads (10%) | called by muse, mutect2, varscan2
- CEBPD | c.634G>T p.A212S | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CFAP58 | c.1461A>T p.Q487H | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); called by muse, varscan2
- CHAT | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 29/243 reads (12%) | called by muse, mutect2, varscan2
- COL15A1 | c.2929C>A p.P977T | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- CPNE5 | c.184-1G>T p.X62_splice | Splice Site (SNP) | VAF 7/97 reads (7%) | called by muse, mutect2
- CTSK | c.190G>T p.A64S | Missense Mutation (SNP) | VAF 42/458 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.35); called by muse, mutect2
- DAB2IP | c.1831A>T p.I611F (on ENST00000408936; = p.I583F on NM_032552.3) | Missense Mutation (SNP) | VAF 20/438 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2
- DEFB129 | c.194A>C p.N65T | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DENND1A | c.97G>C p.V33L | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.02); called by muse, mutect2
- DHX8 | c.2763G>T p.Q921H | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAJC22 | c.634G>T p.A212S | Missense Mutation (SNP) | VAF 41/245 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- DPP10 | c.2281G>C p.V761L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DZIP1 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- EIF6 | c.233A>T p.D78V | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EYA1 | c.1360+1G>A p.X454_splice | Splice Site (SNP) | VAF 26/342 reads (8%) | called by muse, mutect2
- FGFBP1 | c.184A>T p.T62S | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- FLG2 | c.2668G>T p.G890C | Missense Mutation (SNP) | VAF 57/637 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); called by muse, mutect2
- FLNA | c.4328A>G p.H1443R | Missense Mutation (SNP) | VAF 46/239 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPRASP2 | c.218G>T p.R73M | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- HBP1 | c.1100T>C p.V367A | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- HDAC9 | c.3103G>T p.E1035* (on ENST00000441542 / NM_178425.3; = p.E1032* on NM_178423.3) | Nonsense Mutation (SNP) | VAF 36/350 reads (10%) | called by muse, mutect2, varscan2
- HIVEP3 | c.6325G>A p.D2109N | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- HRH2 | c.738C>A p.C246* | Nonsense Mutation (SNP) | VAF 28/257 reads (11%) | called by muse, mutect2, varscan2
- KIF1A | c.31C>G p.R11G | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KISS1R | c.942C>A p.S314R | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- KRTAP10-4 | c.364C>A p.P122T | Missense Mutation (SNP) | VAF 20/554 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- KRTAP29-1 | c.130C>G p.Q44E | Missense Mutation (SNP) | VAF 35/279 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- LATS2 | c.1197C>A p.D399E | Missense Mutation (SNP) | VAF 11/250 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- LRRK2 | c.7207G>T p.E2403* | Nonsense Mutation (SNP) | VAF 18/140 reads (13%) | called by muse, mutect2, varscan2
- MAGEB6B | c.663G>T p.M221I | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- MAP2 | c.2872G>T p.D958Y | Missense Mutation (SNP) | VAF 31/210 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- MATN3 | c.997T>C p.C333R | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- MCF2 | c.1805G>A p.W602* | Nonsense Mutation (SNP) | VAF 10/145 reads (7%) | called by muse, mutect2
- MDC1 | c.4384G>T p.D1462Y | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- MERTK | c.1451-2A>T p.X484_splice | Splice Site (SNP) | VAF 32/632 reads (5%) | called by muse, mutect2
- MOSPD2 | c.906A>T p.K302N | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); called by muse, varscan2
- MUC5B | c.9251C>T p.T3084I | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- MYRIP | c.2204C>A p.A735E | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NEDD4L | c.1610G>T p.R537L (on ENST00000400345 / NM_001144967.3; = p.R517L on NM_015277.6) | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.119); called by muse, mutect2
- NEIL3 | c.1564G>T p.D522Y | Missense Mutation (SNP) | VAF 13/233 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2
- NLRP12 | c.2244G>T p.R748S | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.009); called by muse, mutect2
- NMS | c.262-1G>A p.X88_splice | Splice Site (SNP) | VAF 11/88 reads (13%) | called by muse, mutect2, varscan2
- NOP58 | c.6G>T p.L2F | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- NTF3 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 33/249 reads (13%) | called by muse, mutect2, varscan2
- OCIAD1 | c.722A>G p.D241G | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- OR14A2 | c.281G>A p.G94E | Missense Mutation (SNP) | VAF 22/245 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- OR51Q1 | c.793C>A p.R265S | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- P2RX7 | c.1110G>C p.W370C | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- P2RY8 | c.846C>A p.S282R | Missense Mutation (SNP) | VAF 40/404 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- PCDH15 | c.4034A>G p.Y1345C | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- PELI2 | c.1169C>T p.T390I | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- POM121L12 | c.184C>A p.H62N | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRICKLE2 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 36/322 reads (11%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PSG7 | c.1040G>T p.G347V | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); called by muse, mutect2
- PTPRZ1 | c.4622C>A p.A1541E | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- RIMS2 | c.687dup p.A230Sfs*16 | Frame Shift Ins (INS) | VAF 8/95 reads (8%) | called by mutect2, pindel
- SAMHD1 | c.850T>C p.L284= | Splice Region (SNP) | VAF 8/103 reads (8%) | called by muse, mutect2
- SDK1 | c.5660G>T p.G1887V | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SIX3 | c.347C>A p.P116H | Missense Mutation (SNP) | VAF 41/312 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SKOR1 | c.2516-1G>T p.X839_splice | Splice Site (SNP) | VAF 15/137 reads (11%) | called by muse, mutect2, varscan2
- SLC2A13 | c.137A>G p.E46G | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- SLC4A10 | c.515G>C p.S172T | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.162); called by muse, mutect2
- SMG8 | c.2338C>T p.H780Y | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- SPDYE5 | c.440G>A p.W147* | Nonsense Mutation (SNP) | VAF 30/515 reads (6%) | called by muse, mutect2
- SPTA1 | c.5699C>G p.S1900C | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- TBCD | c.1179A>T p.R393S | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2
- TBL1X | c.1076A>G p.H359R | Missense Mutation (SNP) | VAF 22/314 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.065); called by muse, mutect2
- TDRD6 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- TG | c.244G>T p.G82C | Missense Mutation (SNP) | VAF 40/365 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNNT1 | c.826C>A p.R276S | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TPO | c.1061C>G p.A354G | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- TRHDE | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 41/337 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TSGA10IP | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 13/189 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.138); called by muse, mutect2
- TTN | c.15391G>T p.E5131* (on ENST00000591111; = p.E4204* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- UBASH3B | c.116C>A p.S39* | Nonsense Mutation (SNP) | VAF 19/202 reads (9%) | called by muse, mutect2, varscan2
- VIT | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.039); called by muse, mutect2
- WNT5A | c.820G>T p.A274S | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- ZFHX4 | c.7001A>T p.Q2334L | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF735 | c.793G>C p.G265R | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, varscan2
- ZNF735 | c.836G>A p.R279K | Missense Mutation (SNP) | VAF 30/211 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.09); called by muse, varscan2
- ACTRT1 | c.957A>G p.E319= | Silent (SNP) | VAF 20/180 reads (11%) | called by muse, mutect2, varscan2
- AFF3 | c.3300C>A p.A1100= | Silent (SNP) | VAF 24/247 reads (10%) | catalogued as COSV57867268; called by muse, mutect2, varscan2
- BCAR1 | c.21G>T p.L7= | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- C1orf35 | c.211C>A p.R71= | Silent (SNP) | VAF 28/124 reads (23%) | called by muse, mutect2, varscan2
- CACNG8 | c.735C>T p.A245= | Silent (SNP) | VAF 26/442 reads (6%) | catalogued as rs1411709857; called by muse, mutect2
- CAMK2G | c.1194G>T p.V398= (on ENST00000423381 / NM_001367518.1; = p.V396= on NM_172171.2 and 8 other RefSeq transcripts) | Silent (SNP) | VAF 17/152 reads (11%) | called by muse, mutect2, varscan2
- CDH7 | c.417T>C p.F139= | Silent (SNP) | VAF 41/401 reads (10%) | catalogued as rs761721425; called by muse, mutect2, varscan2
- CRACR2A | c.1020C>T p.A340= | Silent (SNP) | VAF 27/334 reads (8%) | catalogued as COSV52910008; called by muse, mutect2
- CSMD3 | c.1806C>A p.T602= (on ENST00000297405 / NM_001363185.1; = p.T498= on NM_052900.3) | Silent (SNP) | VAF 48/422 reads (11%) | called by muse, mutect2, varscan2
- DMAC2L | c.621G>T p.A207= | Silent (SNP) | VAF 25/218 reads (11%) | called by muse, mutect2, varscan2
- FLRT2 | c.714A>T p.V238= | Silent (SNP) | VAF 18/129 reads (14%) | catalogued as COSV100421261; called by muse, mutect2, varscan2
- GDF5 | c.840G>T p.V280= | Silent (SNP) | VAF 3/24 reads (13%) | called by muse, mutect2
- HPDL | c.231C>T p.S77= | Silent (SNP) | VAF 20/162 reads (12%) | called by muse, mutect2, varscan2
- HSP90AB1 | c.123G>T p.R41= | Silent (SNP) | VAF 23/164 reads (14%) | called by muse, mutect2, varscan2
- KARS1 | c.411T>C p.A137= | Silent (SNP) | VAF 16/194 reads (8%) | called by muse, mutect2
- KIF26B | c.5499G>T p.G1833= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as rs959487794; called by muse, mutect2
- LAMA2 | c.798T>A p.I266= | Silent (SNP) | VAF 37/307 reads (12%) | called by muse, mutect2, varscan2
- MAPK7 | c.1275C>T p.P425= | Silent (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- NEK5 | c.1467G>A p.G489= | Silent (SNP) | VAF 18/190 reads (9%) | called by muse, mutect2
- NLRP2 | c.1320C>A p.G440= | Silent (SNP) | VAF 14/230 reads (6%) | catalogued as COSV99672477; called by muse, mutect2
- OR5A1 | c.111C>A p.I37= | Silent (SNP) | VAF 30/306 reads (10%) | catalogued as COSV100118496; called by muse, mutect2
- OSM | c.258C>G p.T86= | Silent (SNP) | VAF 33/179 reads (18%) | called by muse, mutect2, varscan2
- PAX3 | c.1230C>T p.Y410= | Silent (SNP) | VAF 31/245 reads (13%) | catalogued as rs147111779; called by muse, mutect2, varscan2
- PCARE | c.2529C>T p.F843= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs530658239, COSV59056724; called by muse, mutect2, varscan2
- PCDH15 | c.4083C>A p.T1361= | Silent (SNP) | VAF 46/430 reads (11%) | called by muse, mutect2, varscan2
- PFKFB1 | c.1374G>T p.R458= | Silent (SNP) | VAF 24/274 reads (9%) | called by muse, mutect2
- SLC16A14 | c.1068G>T p.T356= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV99725966; called by muse, mutect2, varscan2
- SLC6A5 | c.1704C>T p.F568= | Silent (SNP) | VAF 63/582 reads (11%) | catalogued as rs1348780417; called by muse, mutect2, varscan2
- SLC6A5 | c.1705C>T p.L569= | Silent (SNP) | VAF 64/583 reads (11%) | called by muse, mutect2, varscan2
- TBX10 | c.441C>T p.R147= | Silent (SNP) | VAF 24/134 reads (18%) | catalogued as rs1565234085; called by muse, mutect2, varscan2
- TRBV2 | c.186C>A p.V62= | Silent (SNP) | VAF 27/246 reads (11%) | called by muse, mutect2, varscan2
- TRPV5 | c.432T>C p.S144= | Silent (SNP) | VAF 24/200 reads (12%) | catalogued as rs1211366489, COSV99521181; called by muse, mutect2, varscan2
- TSPYL2 | c.1041C>A p.G347= | Silent (SNP) | VAF 22/198 reads (11%) | called by muse, mutect2, varscan2
- VPS13A | c.2250G>T p.L750= | Silent (SNP) | VAF 20/335 reads (6%) | called by muse, mutect2
- WDR11 | c.2223A>C p.V741= | Silent (SNP) | VAF 39/243 reads (16%) | called by muse, mutect2, varscan2
- YEATS2 | c.945C>T p.G315= | Silent (SNP) | VAF 9/101 reads (9%) | called by muse, mutect2
- AC009120.4 | n.81C>T | RNA (SNP) | VAF 22/129 reads (17%) | called by muse, mutect2, varscan2
- AC092818.1 | n.408C>A | RNA (SNP) | VAF 20/284 reads (7%) | called by muse, mutect2
- AJAP1 | c.-54del | 5'UTR (DEL) | VAF 14/120 reads (12%) | catalogued as COSV100981867; called by mutect2, pindel, varscan2
- APOOP5 | n.340del | RNA (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- DIAPH1 | c.3662-1973C>T | Intron (SNP) | VAF 26/265 reads (10%) | called by muse, varscan2
- DNAL1 | c.-4C>T | 5'UTR (SNP) | VAF 27/212 reads (13%) | catalogued as COSV100225831; called by muse, mutect2, varscan2
- DSCR4 | n.168C>A | RNA (SNP) | VAF 10/212 reads (5%) | catalogued as COSV100077402; called by muse, mutect2
- DSCR4 | n.167C>A | RNA (SNP) | VAF 10/215 reads (5%) | catalogued as COSV99071269; called by muse, mutect2
- ENPP2 | c.-4C>A | 5'UTR (SNP) | VAF 24/252 reads (10%) | called by muse, varscan2
- ESRRG | c.56+15807G>T | Intron (SNP) | VAF 28/272 reads (10%) | called by muse, mutect2, varscan2
- EXT2 | c.-77G>C | 5'UTR (SNP) | VAF 30/317 reads (9%) | called by muse, mutect2
- FBN2 | c.4471+23C>G | Intron (SNP) | VAF 48/551 reads (9%) | called by muse, mutect2
- INPP4B | c.372+18835C>G | Intron (SNP) | VAF 14/122 reads (11%) | called by muse, mutect2, varscan2
- LAMTOR4 | c.202+138C>T | Intron (SNP) | VAF 31/191 reads (16%) | called by muse, mutect2, varscan2
- OR3A4P | n.1002C>A | RNA (SNP) | VAF 23/168 reads (14%) | called by muse, mutect2, varscan2
- PPDPFL | c.*623T>A | 3'UTR (SNP) | VAF 37/345 reads (11%) | called by muse, mutect2, varscan2
- PRSS40A | n.317+49C>T | Intron (SNP) | VAF 18/330 reads (5%) | called by muse, mutect2
- RPS4XP21 | n.387T>C | RNA (SNP) | VAF 12/78 reads (15%) | called by muse, mutect2, varscan2
- SLC6A8 | c.778-368C>A | Intron (SNP) | VAF 18/149 reads (12%) | called by muse, mutect2, varscan2
- SPACA7 | c.*11C>T | 3'UTR (SNP) | VAF 15/115 reads (13%) | called by muse, mutect2, varscan2
